Somatic mutation profile of tumor specimen 0DZ39V from CCDI case PBCTPH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Overlapping lesion of rectum, anus and anal canal; Age at diagnosis: 14.5 years (5,306 days).
Specimen 0DZ39V: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14d43c51-9b95-4329-80c6-6967a39e754b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZ3A1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ca33ccb-39ef-4c2e-bb0f-5d4763c8e874

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 4, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 179/503 reads (36%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- CAPN6 | c.1583T>C p.L528P | Missense Mutation (SNP) | VAF 183/905 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1168273037; called by muse, mutect2, varscan2
- CHERP | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 133/309 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs935661382; called by muse, mutect2, varscan2
- CPLX4 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 277/676 reads (41%) | catalogued as COSV104409774, COSV55313570, COSV55313932; called by mutect2, varscan2
- FFAR3 | c.754G>A p.G252S | Missense Mutation (SNP) | VAF 498/1795 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.075); catalogued as rs540255880, COSV100588334; called by muse, mutect2, varscan2
- H2AC11 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 71/660 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (1); catalogued as rs1465528345; called by muse, mutect2, varscan2
- NPIPB15 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 34/383 reads (9%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs374113246; called by muse, mutect2, varscan2
- SETD2 | c.7435T>A p.S2479T | Missense Mutation (SNP) | VAF 170/388 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV57456420; called by muse, varscan2
- USP21 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 575/1333 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as rs761658917; called by muse, mutect2, varscan2
- MLLT10 | c.3064_3065del p.N1022Qfs*26 | Frame Shift Del (DEL) | VAF 472/1100 reads (43%) | called by mutect2, varscan2
- PRAMEF12 | c.774C>G p.F258L | Missense Mutation (SNP) | VAF 306/729 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ZDHHC15 | c.769C>G p.P257A | Missense Mutation (SNP) | VAF 478/1044 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- CERCAM | c.427-15G>A | Intron (SNP) | VAF 30/152 reads (20%) | catalogued as rs777170138; called by muse, mutect2, varscan2
- EEF1AKMT2 | c.292-25A>T | Intron (SNP) | VAF 12/260 reads (5%) | called by muse, mutect2
- EIF3F | c.653+55C>T | Intron (SNP) | VAF 80/167 reads (48%) | called by muse, mutect2, varscan2
- PIKFYVE | c.1320+67G>A | Intron (SNP) | VAF 91/203 reads (45%) | called by muse, mutect2, varscan2
